Somatic mutation profile of tumor specimen MP2PRT-PAVHWD-TMP1-A (aliquot MP2PRT-PAVHWD-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVHWD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,299 days).
Specimen MP2PRT-PAVHWD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59635ef2-f423-4b90-9460-4fff3e4fe18f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHWD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHWD-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d759ad2f-e741-44d7-8aa1-11261d507e68

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 51/281 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TMEM170A | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1346944599, COSV62923323; called by muse, mutect2, varscan2
- ZNF280C | c.1830G>T p.K610N | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as COSV63969899; called by muse, mutect2, varscan2
- ADCK5 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 29/435 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ATP6V0A1 | c.1492C>G p.P498A | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP99 | c.1111C>G p.Q371E | Missense Mutation (SNP) | VAF 156/317 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- FBXO11 | c.2090_2101delinsCCCTGGC p.G697Afs*5 (on ENST00000403359 / NM_001190274.2; = p.G613Afs*5 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 43/175 reads (25%) | called by pindel, varscan2*
- IGKJ2 | chr2:88861553 AAAACTGCACACACAAT>CGGG | Missense Mutation (DEL) | VAF 16/67 reads (24%) | called by pindel, varscan2*
- TRPC6 | c.381C>G p.N127K | Missense Mutation (SNP) | VAF 28/375 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFP36L2 | c.1341dup p.S448Qfs*26 | Frame Shift Ins (INS) | VAF 114/655 reads (17%) | called by mutect2, pindel, varscan2
- C8A | c.1395C>T p.H465= | Silent (SNP) | VAF 27/376 reads (7%) | catalogued as rs201408238; called by muse, mutect2
- NPAP1L | n.862C>T | RNA (SNP) | VAF 65/232 reads (28%) | called by muse, mutect2, varscan2
